Gene-level copy-number profile of tumor specimen TCGA-BA-6869-01A from TCGA case TCGA-BA-6869, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.3 years (22,765 days).
Specimen TCGA-BA-6869-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.184acfcd-ebde-4882-888a-5384c51d0d98.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-6869-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b2f3f0d6-1927-423d-98b3-3ed9f0c9e910

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 7,567; copy number 2: 47,689; copy number 3: 1,674; copy number 4: 1,896; copy number 5: 603; copy number 6: 1; copy number 7: 10; copy number 9: 376; copy number 10: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-6869-01A-11D-1869-01): tumor purity 0.64, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:144,706,733–144,708,497, 2 genes: AL513475.1, AL513475.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 992 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:1,957,589–37,602,974, 610 genes, copy number 5–10 (broad region; genes not listed).
- chr16:7,126,293–7,126,639, 1 gene, copy number 6: AC022206.1.
- chr18:47,390–15,330,282, 376 genes, copy number 9 (broad region; genes not listed).
- chr18:77,863,464–78,140,887, 5 genes, copy number 5: RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1.

Autosomal genes at a single copy (total copy number 1): 5,152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
